CCDI case PBBPGU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/dc6af073-f21b-4434-a1e7-752478247399

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.3 years (5,578 days).

Biospecimens (3 samples)
- Sample 0DDZ5Z: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DDZ6Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DEK15: Tissue type: Tumor; Specimen type: Solid Tissue.
